Somatic mutation profile of tumor specimen 0DHOJ4 from CCDI case PBBUDK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.0 years (1,833 days).
Specimen 0DHOJ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1fd37a8-40d0-497a-9b17-042dd1175d82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHOGT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/449e8c80-62d5-4aa0-b588-4a987bc41c83

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 3, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CROCC | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 156/312 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs397834615, COSV65009703, COSV65013695; called by muse, varscan2
- H3C3 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 215/448 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63551114; called by muse, varscan2
- IL16 | c.3876G>A p.M1292I (on ENST00000302987 / NM_172217.5; = p.M591I on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV100250674; called by muse, varscan2
- MEFV | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.822); catalogued as rs760804547, COSV54824236; called by muse, varscan2
- NLGN4X | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 134/326 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1362464602, COSV52039844; called by muse, varscan2
- OVCH1 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 91/424 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771819253, COSV58965474; called by muse, varscan2
- PROM1 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 110/516 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71699647; called by muse, varscan2
- ZNF628 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs373480260; called by muse, varscan2
- ATAD3B | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.121); called by muse, varscan2
- DUSP8 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); called by muse, varscan2
- RAPGEF6 | c.2462G>A p.R821K | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); called by muse, varscan2
- MUC22 | c.2160C>T p.T720= | Silent (SNP) | VAF 114/534 reads (21%) | catalogued as rs1235167486; called by muse, varscan2
- PRDM16 | c.1485G>A p.P495= | Silent (SNP) | VAF 80/160 reads (50%) | catalogued as rs370666366; ClinVar: uncertain significance; called by muse, varscan2
- BCAR3 | c.1975-83C>G | Intron (SNP) | VAF 13/86 reads (15%) | called by muse, varscan2
- CGA | c.89-92A>G | Intron (SNP) | VAF 16/108 reads (15%) | catalogued as rs1162348041, COSV63644153; called by muse, varscan2
- EXOSC10 | c.1880-97T>C | Intron (SNP) | VAF 10/85 reads (12%) | called by muse, varscan2
- GJD4 | c.*48A>G | 3'UTR (SNP) | VAF 32/197 reads (16%) | called by muse, varscan2
